Somatic mutation profile of tumor specimen TCGA-FR-A7U9-06A (aliquot TCGA-FR-A7U9-06A-11D-A34U-08) from TCGA case TCGA-FR-A7U9, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 63.8 years (23,295 days).
Specimen TCGA-FR-A7U9-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c3329a0d-f3a6-4bd1-807f-ac4d0de5882f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FR-A7U9-10A (Blood Derived Normal), aliquot TCGA-FR-A7U9-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/420ac47a-09c4-4448-8f19-5d9eaa25a0f3

The open-access MAF lists 2,122 somatic variants for this specimen: 1,403 protein-altering or splice-affecting, 672 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,287, Silent 672, Nonsense Mutation 90, Intron 17, RNA 14, Splice Region 11, Splice Site 9, 3'UTR 8, Translation Start Site 4, 3'Flank 4, Frame Shift Del 2, 5'UTR 2.

Variants (750 of 2,122; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 29/108 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as CM970251, COSV100446243, COSV58683273, COSV58688196; called by muse, mutect2, varscan2
- CFTR | c.3196C>T p.R1066C | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs78194216, CM1212243, CM920175, CM952054, COSV50055196; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KDR | c.3095G>A p.R1032Q | Missense Mutation (SNP) | VAF 19/86 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1190050670, COSV55758808; called by muse, mutect2, varscan2
- NF1 | c.4183C>T p.Q1395* (on ENST00000358273 / NM_001042492.3; = p.Q1374* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 33/91 reads (36%) | catalogued as rs1555618494, CM135603, COSV100647883; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PRKN | c.1358G>A p.W453* | Nonsense Mutation (SNP) | VAF 5/20 reads (25%) | catalogued as rs137853056, CM991009, COSV58222532, COSV58229738; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 6/29 reads (21%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1BG | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs781336739, COSV54052340, COSV99568538; called by muse, mutect2, varscan2
- A2M | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.356); catalogued as COSV100588874; called by muse, mutect2, varscan2
- AASDH | c.1817C>T p.S606L | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs761563475, COSV99221666; called by muse, mutect2, varscan2
- ABCA10 | c.92A>G p.K31R | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV99289120; called by muse, mutect2, varscan2
- ABCA12 | c.4021G>A p.D1341N (on ENST00000272895 / NM_173076.3; = p.D1023N on NM_015657.3) | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as COSV99791291; called by muse, mutect2, varscan2
- ABCA4 | c.1099+1G>C p.X367_splice | Splice Site (SNP) | VAF 15/93 reads (16%) | catalogued as CS132929, COSV100933183; called by muse, mutect2, varscan2
- ABCA4 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs868543294, CM161614, COSV100933100; called by muse, mutect2, varscan2
- ABCC6 | c.677G>A p.G226E | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1210571370, COSV99229312; called by muse, mutect2, varscan2
- ABCC9 | c.746G>A p.G249E | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs865881159, COSV53983935; called by muse, mutect2, varscan2
- ABCD4 | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as COSV100084449; called by muse, mutect2, varscan2
- ABCG8 | c.302T>C p.L101P | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99700111; called by muse, mutect2, varscan2
- ABI2 | c.1467T>G p.Y489* (on ENST00000295851 / NM_001375719.1; = p.Y451* on NM_005759.7 and 35 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 17/57 reads (30%) | catalogued as COSV99652110; called by muse, mutect2, varscan2
- ABL2 | c.2012C>T p.S671F (on ENST00000502732 / NM_007314.4; = p.S656F on NM_005158.5) | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as rs866259173, COSV100772904; called by muse, mutect2, varscan2
- ABO | c.52C>T p.R18* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as rs782542998, COSV101505918; called by muse, mutect2
- ACACB | c.6713A>G p.K2238R | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as COSV100623155; called by muse, mutect2, varscan2
- ACADVL | c.1763C>A p.S588Y | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99138721; called by muse, mutect2, varscan2
- ACAN | c.7602G>A p.W2534* (on ENST00000560601 / NM_001369268.1; = p.W2496* on NM_013227.3) | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as COSV100613841; called by muse, varscan2
- ACAN | c.7610C>T p.P2537L (on ENST00000560601 / NM_001369268.1; = p.P2499L on NM_013227.3) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100613842; called by muse, varscan2
- ACKR2 | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV56181022; called by muse, mutect2, varscan2
- ACSF2 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs781188170, COSV51971814; called by muse, mutect2, varscan2
- ACSM2B | c.1189G>A p.D397N | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV61657129; called by muse, mutect2, varscan2
- ACSM2B | c.1060G>A p.G354R | Missense Mutation (SNP) | VAF 44/179 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61659342; called by muse, mutect2, varscan2
- ACSM2B | c.968T>A p.L323H | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100313021; called by muse, mutect2, varscan2
- ACTL8 | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.02); catalogued as rs886522728, COSV64861479, COSV64862066; called by muse, mutect2, varscan2
- ACTN1 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99518293; called by muse, varscan2
- ACTN4 | c.2552C>T p.S851F | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53142861, COSV53144677; called by muse, mutect2, varscan2
- ACVR2A | c.1132C>T p.Q378* | Nonsense Mutation (SNP) | VAF 20/119 reads (17%) | catalogued as COSV99604865; called by muse, mutect2, varscan2
- ACVRL1 | c.806C>T p.S269L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101188046; called by muse, mutect2, varscan2
- ADAM18 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV99695955; called by muse, mutect2, varscan2
- ADAM18 | c.2013A>T p.K671N | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.171); catalogued as COSV99695956; called by muse, mutect2, varscan2
- ADAM23 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.148); catalogued as rs148692770, COSV52225138; called by muse, mutect2, varscan2
- ADAM29 | c.2272C>T p.Q758* | Nonsense Mutation (SNP) | VAF 18/86 reads (21%) | catalogued as COSV100822177; called by muse, mutect2, varscan2
- ADAM32 | c.840G>A p.M280I | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV101165453; called by muse, mutect2, varscan2
- ADAM33 | c.1487C>T p.P496L | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1203116461, COSV100598000, COSV100598089; called by muse, varscan2
- ADAMTS10 | c.2276G>A p.G759E | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99547271; called by muse, mutect2, varscan2
- ADAMTS10 | c.2275G>A p.G759R | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99547273; called by muse, mutect2, varscan2
- ADAMTS12 | c.3916A>C p.K1306Q | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV100711485; called by muse, mutect2, varscan2
- ADAMTS13 | c.2790A>T p.E930D | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.174); catalogued as COSV100747164; called by muse, mutect2, varscan2
- ADAMTS16 | c.566G>A p.W189* | Nonsense Mutation (SNP) | VAF 26/93 reads (28%) | catalogued as COSV99942257; called by muse, mutect2, varscan2
- ADAMTS16 | c.567G>A p.W189* | Nonsense Mutation (SNP) | VAF 26/93 reads (28%) | catalogued as COSV99942260; called by muse, mutect2, varscan2
- ADAMTS16 | c.2303C>T p.P768L | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372938401; called by muse, mutect2, varscan2
- ADAMTS18 | c.547C>T p.Q183* | Nonsense Mutation (SNP) | VAF 8/60 reads (13%) | catalogued as COSV99273721; called by muse, mutect2
- ADAMTS7 | c.1274C>T p.P425L | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.721); catalogued as COSV66309661; called by muse, mutect2, varscan2
- ADCY4 | c.2842G>A p.D948N | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV100156748, COSV60254754; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV58445354; called by muse, mutect2, varscan2
- ADD3 | c.1092G>A p.W364* | Nonsense Mutation (SNP) | VAF 13/94 reads (14%) | catalogued as COSV99523606; called by muse, mutect2, varscan2
- ADGRA2 | c.717C>T p.C239= | Splice Region (SNP) | VAF 5/17 reads (29%) | catalogued as rs1411680159, COSV100178303; called by muse, mutect2
- ADGRF1 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV100982660; called by muse, mutect2, varscan2
- ADGRG4 | c.3791C>T p.S1264F | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.543); catalogued as COSV99796267; called by muse, mutect2, varscan2
- ADGRL2 | c.2613T>A p.F871L (on ENST00000370717 / NM_001366005.1; = p.F858L on NM_012302.4) | Missense Mutation (SNP) | VAF 47/170 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.95); catalogued as COSV99590639; called by muse, mutect2, varscan2
- ADGRV1 | c.6026G>A p.G2009E | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67981163; called by muse, mutect2, varscan2
- ADH1A | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 35/190 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99265914; called by muse, mutect2, varscan2
- ADH1B | c.1112C>T p.T371I | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as COSV100520829, COSV59295344; called by muse, mutect2, varscan2
- ADH1B | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.471); catalogued as rs770117532, COSV59295307; called by muse, mutect2, varscan2
- ADH7 | c.436G>A p.G146S | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV52922140; called by muse, mutect2, varscan2
- AFAP1 | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.078); catalogued as COSV100631950; called by muse, mutect2, varscan2
- AGBL1 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1272840873, COSV69800737; called by muse, mutect2
- AGTR1 | c.805G>A p.G269S | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0.292); catalogued as rs762651737, COSV100837122; called by muse, mutect2, varscan2
- AGTR2 | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64156397; called by muse, mutect2, varscan2
- AHNAK2 | c.10334C>T p.A3445V | Missense Mutation (SNP) | VAF 87/357 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.134); catalogued as rs1334875475, COSV100318493; called by muse, mutect2, varscan2
- AKR1D1 | c.50G>A p.S17N | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99653213; called by muse, mutect2, varscan2
- AKR7A3 | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as COSV64389081; called by muse, mutect2, varscan2
- ALG13 | c.1736C>T p.S579L | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV99322791; called by muse, mutect2, varscan2
- ALK | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1450440625, COSV66561234, COSV66577327; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALPK1 | c.1636C>T p.R546* | Nonsense Mutation (SNP) | VAF 7/35 reads (20%) | catalogued as rs1388112183, COSV51581917; called by muse, mutect2, varscan2
- ALPK2 | c.2875G>A p.G959R | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.706); catalogued as COSV100864689; called by muse, mutect2, varscan2
- ALPL | c.1417G>A p.G473S | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as CM980080, COSV66376712; called by muse, mutect2, varscan2
- AMPD3 | c.1579G>A p.D527N (on ENST00000396553 / NM_001025389.2; = p.D536N on NM_000480.3) | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101158223; called by muse, mutect2, varscan2
- AMPH | c.1723C>T p.P575S | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV57731962, COSV57759788; called by muse, mutect2, varscan2
- AMTN | c.550G>A p.V184M | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.02); catalogued as COSV59490097; called by muse, varscan2
- AMZ1 | c.1480G>A p.D494N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.017); catalogued as COSV100406539; called by muse, mutect2
- ANAPC1 | c.4525C>T p.P1509S | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100594975; called by muse, mutect2, varscan2
- ANAPC1 | c.2194C>T p.P732S | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100594976; called by muse, mutect2, varscan2
- ANAPC7 | c.983G>A p.G328E | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.413); catalogued as rs1173016525, COSV101482872; called by muse, mutect2, varscan2
- ANAPC7 | c.982G>A p.G328R | Missense Mutation (SNP) | VAF 33/186 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.592); catalogued as COSV101482873; called by muse, mutect2, varscan2
- ANK1 | c.5566G>A p.E1856K | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.006); catalogued as COSV99226288; called by muse, mutect2, varscan2
- ANK1 | c.3239G>A p.G1080E | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99226292; called by muse, mutect2, varscan2
- ANK3 | c.12809C>T p.S4270F (on ENST00000280772 / NM_001320874.2; = p.S894F on NM_001149.3) | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); catalogued as COSV99781503; called by muse, mutect2, varscan2
- ANK3 | c.10687G>A p.E3563K | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.073); catalogued as COSV55053099; called by mutect2, varscan2
- ANK3 | c.9488G>A p.G3163E | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); catalogued as COSV99781517; called by muse, mutect2, varscan2
- ANKH | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.27); catalogued as rs986240035, COSV99414360; called by muse, mutect2, varscan2
- ANKRD30A | c.2909C>T p.S970F (on ENST00000611781; = p.S914F on NM_052997.2) | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.732); catalogued as COSV64607518; called by muse, mutect2
- ANKRD35 | c.368C>T p.P123L | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100841817; called by muse, mutect2, varscan2
- ANKS4B | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV100289904; called by muse, mutect2, varscan2
- ANO2 | c.2429C>T p.S810F (on ENST00000356134 / NM_001278597.3; = p.S814F on NM_001278596.3) | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59034881; called by muse, mutect2, varscan2
- ANO8 | c.2503C>T p.P835S | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99344783; called by muse, mutect2
- ANOS1 | c.2036G>A p.R679K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV52923272, COSV99391244; called by muse, mutect2, varscan2
- ANOS1 | c.1484C>T p.S495F | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99391247; called by muse, mutect2, varscan2
- ANXA11 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.014); catalogued as rs960214482, COSV99627407; called by muse, mutect2
- ANXA9 | c.787G>A p.G263S | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs587751896, COSV64485106; called by muse, mutect2, varscan2
- AOX1 | c.2954C>T p.S985F | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs1363049970, COSV101022177; called by muse, mutect2, varscan2
- APCS | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99661194; called by muse, mutect2, varscan2
- APMAP | c.1000T>A p.F334I | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV99468923; called by muse, varscan2
- APOA1 | c.288G>A p.W96* | Nonsense Mutation (SNP) | VAF 8/47 reads (17%) | catalogued as COSV99369342; called by muse, mutect2, varscan2
- APOB | c.12059C>T p.S4020F | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs891761042, COSV99267076; called by muse, mutect2, varscan2
- APOB | c.3527T>C p.F1176S | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51958081, COSV99267081; called by muse, mutect2, varscan2
- APOL3 | c.554C>T p.T185I (on ENST00000349314 / NM_145640.2; = p.T114I on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV100652142; called by muse, varscan2
- APOL3 | c.469C>T p.P157S (on ENST00000349314 / NM_145640.2; = p.P86S on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV62580721; called by muse, varscan2
- ARAP2 | c.1280G>A p.R427K | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.444); catalogued as COSV100394047, COSV58292047; called by muse, mutect2, varscan2
- ARFGEF3 | c.5782G>A p.E1928K | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as COSV52460699; called by muse, mutect2, varscan2
- ARHGAP10 | c.1925C>T p.S642F | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); catalogued as rs1447375535, COSV100331608; called by muse, mutect2, varscan2
- ARHGAP19 | c.1036C>T p.Q346* | Nonsense Mutation (SNP) | VAF 19/62 reads (31%) | catalogued as COSV100363276; called by muse, mutect2, varscan2
- ARHGAP22 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.99); PolyPhen benign (0.02); catalogued as rs1027250027, COSV50945462; called by muse, mutect2, varscan2
- ARHGAP31 | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99957507; called by muse, mutect2, varscan2
- ARHGAP44 | c.1336C>T p.P446S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99310676; called by muse, mutect2, varscan2
- ARHGAP6 | c.1721C>T p.S574L | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as COSV100273392; called by muse, mutect2, varscan2
- ARID4A | c.3410T>C p.L1137P | Missense Mutation (SNP) | VAF 46/189 reads (24%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.771); catalogued as COSV100794538; called by muse, mutect2, varscan2
- ARID5A | c.173A>C p.E58A | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100673632; called by muse, mutect2, varscan2
- ARMC12 | c.956C>T p.P319L (on ENST00000373866 / NM_001286574.2; = p.P346L on NM_145028.5) | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.149); catalogued as COSV99849549; called by muse, mutect2, varscan2
- ARMC4 | c.1396C>T p.Q466* | Nonsense Mutation (SNP) | VAF 24/59 reads (41%) | catalogued as COSV59475161; called by muse, mutect2, varscan2
- ARSF | c.1177G>A p.A393T | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.121); catalogued as COSV63840289; called by muse, mutect2, varscan2
- ART1 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as COSV99167227; called by muse, mutect2, varscan2
- ASTN2 | c.1579G>A p.D527N (on ENST00000313400 / NM_001365069.1; = p.D476N on NM_014010.5) | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as rs976057171, COSV57747261; called by muse, varscan2
- ASXL2 | c.982A>C p.N328H | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99711774; called by muse, mutect2, varscan2
- ASXL3 | c.1157C>T p.S386L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs1411631905, COSV52457881; called by muse, mutect2, varscan2
- ASXL3 | c.1678G>A p.E560K | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.257); catalogued as rs745776273, COSV99325963; called by muse, mutect2, varscan2
- ASXL3 | c.5215C>T p.R1739C | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs376309030; called by muse, mutect2, varscan2
- ATCAY | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as COSV100008933; called by muse, mutect2, varscan2
- ATP10B | c.1084C>T p.L362F | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs781555445, COSV100469632; called by muse, mutect2, varscan2
- ATP11B | c.1544C>T p.S515F | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.608); catalogued as COSV100017996; called by muse, mutect2, varscan2
- ATP11B | c.1726C>T p.R576C | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60027356; called by muse, mutect2
- ATP11C | c.1537T>C p.F513L | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.547); catalogued as COSV100558375; called by muse, mutect2, varscan2
- ATP13A5 | c.1795C>T p.P599S | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100665524; called by muse, mutect2, varscan2
- ATP1A2 | c.2509C>T p.Q837* | Nonsense Mutation (SNP) | VAF 5/34 reads (15%) | catalogued as COSV100768069; called by mutect2, varscan2
- ATP1A4 | c.1939G>A p.A647T | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.314); catalogued as COSV100927617; called by muse, mutect2, varscan2
- ATP2A3 | c.1597C>T p.R533C | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.141); catalogued as rs772480917, COSV99988957; called by muse, mutect2, varscan2
- ATP6V1C2 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 74/284 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs267598832, COSV55365148; called by muse, mutect2, varscan2
- ATP6V1H | c.856C>T p.L286F | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs761171820, COSV62217536; called by muse, mutect2, varscan2
- ATRX | c.5920G>A p.G1974R | Missense Mutation (SNP) | VAF 45/306 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.289); catalogued as rs1013126734, COSV100971230; called by muse, mutect2, varscan2
- ATXN2 | c.3190C>T p.H1064Y (on ENST00000550104; = p.H904Y on NM_002973.4) | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); catalogued as rs202198998, COSV101112882; called by muse, mutect2, varscan2
- AWAT1 | c.605G>A p.G202E | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752202131, COSV100997226; called by muse, mutect2, varscan2
- AXDND1 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV62649980; called by muse, mutect2
- B3GALT1 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as COSV59908505; called by muse, mutect2, varscan2
- BAAT | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV99408583; called by muse, mutect2, varscan2
- BAHD1 | c.1952C>T p.A651V | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs923384929, COSV101346782; called by muse, mutect2, varscan2
- BAZ2A | c.2740C>T p.P914S | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV51631810, COSV99467239; called by muse, mutect2, varscan2
- BCAS1 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 50/226 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV101006367, COSV65085549; called by muse, mutect2, varscan2
- BCL11B | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as COSV61735288; called by muse, mutect2, varscan2
- BCORL1 | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.2); catalogued as COSV99500406; called by muse, mutect2, varscan2
- BEND2 | c.2374C>T p.P792S | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT tolerated (0.75); PolyPhen benign (0.031); catalogued as COSV66219898; called by muse, mutect2, varscan2
- BFAR | c.931G>A p.G311R | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV99902380; called by muse, mutect2, varscan2
- BGN | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV100525257; called by muse, mutect2
- BICDL1 | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV101287435; called by muse, mutect2, varscan2
- BICRAL | c.1756C>T p.R586C | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs144992246; called by muse, mutect2, varscan2
- BRCA2 | c.1478C>T p.P493L | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.89); PolyPhen benign (0.019); catalogued as rs786202916, COSV99061655; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- BRD4 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs1331613863, COSV54587817; called by muse, mutect2, varscan2
- BRDT | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100746550; called by muse, mutect2, varscan2
- BRINP1 | c.1725G>A p.W575* | Nonsense Mutation (SNP) | VAF 12/46 reads (26%) | catalogued as COSV99776460; called by muse, mutect2, varscan2
- BRSK1 | c.2224C>T p.R742* | Nonsense Mutation (SNP) | VAF 6/17 reads (35%) | catalogued as rs759885128, COSV100442316, COSV100442424; called by muse, varscan2
- BTLA | c.62C>A p.P21Q | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.68); catalogued as COSV100569795, COSV57938005; called by muse, mutect2, varscan2
- BUB1 | c.2000C>T p.S667L | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs975621280, COSV57063381; called by muse, mutect2, varscan2
- C10orf90 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.463); catalogued as rs140913571; called by muse, mutect2, varscan2
- C17orf67 | c.57G>A p.E19= | Splice Region (SNP) | VAF 40/254 reads (16%) | catalogued as COSV101191007, COSV67375875; called by muse, mutect2, varscan2
- C1orf109 | c.286C>T p.L96F | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.944); catalogued as COSV100787511; called by muse, mutect2, varscan2
- C1orf87 | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1296198918, COSV100967205; called by mutect2, varscan2
- C3 | c.4484C>A p.P1495Q | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV99836438; called by muse, mutect2, varscan2
- C3orf56 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.224); catalogued as COSV101228976; called by muse, varscan2
- C3orf62 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99649586; called by muse, mutect2, varscan2
- C7 | c.251G>A p.G84E | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1402493470, COSV57470554; called by muse, mutect2, varscan2
- C8A | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs940831429, COSV63483165; called by muse, mutect2, varscan2
- C9orf131 | c.780G>A p.M260I | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.097); catalogued as COSV100398217; called by muse, mutect2, varscan2
- C9orf152 | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV101272397; called by muse, mutect2, varscan2
- C9orf153 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs757701675, COSV59250541, COSV59252014; called by muse, mutect2, varscan2
- CA10 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 88/210 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs767808441, COSV53350762; called by muse, mutect2, varscan2
- CACHD1 | c.3218C>T p.P1073L | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51549157; called by muse, mutect2, varscan2
- CACNA1A | c.137G>A p.R46K | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100803000; called by muse, mutect2
- CACNA1C | c.3074C>T p.A1025V | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100221037; called by muse, mutect2, varscan2
- CACNA1E | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100704424; called by muse, varscan2
- CACNA1E | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV62383253; called by muse, varscan2
- CACNA1E | c.5068G>A p.E1690K | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.31); catalogued as rs569085430, COSV62390649; called by muse, mutect2, varscan2
- CACNA2D3 | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.777); catalogued as COSV99875997; called by muse, mutect2, varscan2
- CACNG3 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99136872; called by muse, mutect2, varscan2
- CADPS2 | c.3452C>T p.S1151L | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV57353711; called by muse, mutect2, varscan2
- CALB1 | c.373-1G>A p.X125_splice | Splice Site (SNP) | VAF 17/56 reads (30%) | catalogued as COSV99618451; called by muse, mutect2, varscan2
- CALCRL | c.442G>A p.G148R | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101131018; called by muse, mutect2, varscan2
- CALR | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.639); catalogued as COSV100330957; called by muse, mutect2, varscan2
- CALR | c.533C>T p.P178L | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1353439888, COSV100330959; called by muse, mutect2, varscan2
- CAP2 | c.1093C>T p.Q365* | Nonsense Mutation (SNP) | VAF 15/67 reads (22%) | catalogued as rs1305730214, COSV100012778; called by muse, mutect2, varscan2
- CAPN6 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV100136996; called by muse, mutect2, varscan2
- CAPZA3 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs769365098, COSV56850079; called by muse, mutect2, varscan2
- CARD18 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs751687288, COSV73233137; called by muse, mutect2, varscan2
- CASR | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.234); catalogued as rs121909262, CM950198, COSV56133823; called by muse, mutect2, varscan2
- CASZ1 | c.2864C>T p.S955F | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1474975765, COSV100681936; called by muse, mutect2, varscan2
- CATSPERB | c.1795G>A p.G599R | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV99831578; called by muse, mutect2, varscan2
- CATSPERB | c.1249C>T p.H417Y | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866512933, COSV56426913; called by muse, varscan2
- CBL | c.1249C>T p.P417S | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867564832, COSV50631687, COSV50635445; called by muse, mutect2, varscan2
- CBLB | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765908020, COSV99913997; called by mutect2, varscan2
- CBLC | c.425G>A p.G142E | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747887583, COSV54322809, COSV99542231; called by muse, mutect2, varscan2
- CBLL2 | c.923C>T p.S308L | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1257570318, COSV60368932; called by muse, mutect2, varscan2
- CBX4 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.924); catalogued as rs774154715, COSV99490480; called by muse, mutect2, varscan2
- CCAR2 | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1246609240, COSV57904116; called by muse, mutect2, varscan2
- CCDC141 | c.2965G>A p.D989N | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as COSV55372235; called by muse, mutect2, varscan2
- CCDC171 | c.1316C>T p.S439L | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as rs1172407585, COSV99901551; called by muse, mutect2, varscan2
- CCDC173 | c.728T>C p.I243T | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV101376715; called by muse, mutect2, varscan2
- CCDC178 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV55765767; called by muse, mutect2, varscan2
- CCDC60 | c.956G>A p.R319K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59544284; called by muse, mutect2, varscan2
- CCDC60 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 25/216 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.167); catalogued as rs1297066120, COSV59540844; called by muse, mutect2, varscan2
- CCK | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs370480453; called by muse, mutect2, varscan2
- CCL7 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.838); catalogued as COSV99565610; called by muse, mutect2, varscan2
- CCNB3 | c.2557G>A p.E853K | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV99329543; called by muse, mutect2, varscan2
- CCNL2 | c.1141C>T p.R381W | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs1017810145, COSV101275709; called by muse, mutect2, varscan2
- CCR1 | c.337T>C p.Y113H | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as rs1198886677, COSV99946778; called by muse, mutect2
- CCSER1 | c.410G>A p.R137K | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV61479136; called by muse, mutect2
- CCT8L2 | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs781458727, COSV100742906, COSV63461758; called by muse, mutect2, varscan2
- CD163 | c.1519T>C p.F507L | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.149); catalogued as COSV100776025; called by muse, mutect2, varscan2
- CD200R1 | c.886G>A p.E296K (on ENST00000471858 / NM_170780.3; = p.E319K on NM_138806.4) | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as COSV99867633; called by muse, mutect2, varscan2
- CD5L | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.809); catalogued as rs762795478, COSV63822024; called by muse, mutect2, varscan2
- CD93 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.749); catalogued as rs759700389, COSV99849446; called by muse, mutect2, varscan2
- CDC23 | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV101203143; called by muse, mutect2, varscan2
- CDCA8 | c.412C>T p.Q138* | Nonsense Mutation (SNP) | VAF 21/107 reads (20%) | catalogued as COSV100523697; called by muse, mutect2, varscan2
- CDH12 | c.2020G>A p.D674N | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765565044, COSV101202350, COSV66397071; called by muse, varscan2
- CDH12 | c.1948A>T p.K650* | Nonsense Mutation (SNP) | VAF 24/60 reads (40%) | catalogued as COSV101203118; called by muse, varscan2
- CDH20 | c.2098G>A p.D700N | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as rs1367667297, COSV99406176; called by muse, mutect2, varscan2
- CDH23 | c.8857G>A p.D2953N | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); catalogued as rs762646673, COSV99821229; called by muse, mutect2
- CDH8 | c.2206C>T p.P736S | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV54875128; called by muse, mutect2, varscan2
- CDKAL1 | c.1548G>A p.K516= | Splice Region (SNP) | VAF 14/57 reads (25%) | catalogued as COSV99216154; called by muse, mutect2, varscan2
- CDKN2A | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.347); catalogued as rs786204195, CM003922, COSV58718173; called by muse, mutect2, varscan2
- CEACAM4 | c.575C>G p.P192R | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV99701151; called by muse, mutect2, varscan2
- CENPF | c.4471G>A p.G1491R | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.16); catalogued as rs745591609, COSV100871862; called by mutect2, varscan2
- CEP135 | c.2003C>T p.S668L | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV99954755; called by muse, mutect2, varscan2
- CEP290 | c.5392C>T p.L1798F | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); catalogued as COSV100469430; called by muse, mutect2, varscan2
- CERS3 | c.1053G>T p.E351D | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as COSV52571508, COSV99432491; called by muse, mutect2
- CFAP206 | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1251263246, COSV51532553; called by muse, mutect2, varscan2
- CFAP44 | c.1105C>T p.P369S | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV99870170; called by muse, varscan2
- CFAP45 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV63649156; called by muse, mutect2, varscan2
- CFAP54 | c.6419G>A p.G2140E | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61573137; called by muse, mutect2, varscan2
- CFAP54 | c.6928G>A p.A2310T | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV100733286; called by muse, mutect2, varscan2
- CHD2 | c.2354C>T p.S785F | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.825); catalogued as COSV101245762; called by muse, mutect2, varscan2
- CHD5 | c.3112G>A p.D1038N | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.242); catalogued as COSV99314511; called by muse, mutect2, varscan2
- CHD5 | c.1492C>T p.P498S | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as rs1224581521, COSV99314513; called by muse, mutect2, varscan2
- CHD6 | c.7855C>T p.P2619S | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV100951267; called by muse, mutect2, varscan2
- CHGB | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as COSV100972926; called by muse, mutect2, varscan2
- CHI3L2 | c.1141C>T p.Q381* | Nonsense Mutation (SNP) | VAF 15/141 reads (11%) | catalogued as COSV100869312; called by muse, mutect2, varscan2
- CHODL | c.317A>T p.N106I | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.05); catalogued as COSV100166982; called by muse, varscan2
- CHRDL2 | c.745A>G p.K249E | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as COSV99734012; called by muse, mutect2, varscan2
- CHRNA2 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.868); catalogued as rs775714882, COSV53559906; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHRNB1 | c.421T>C p.W141R | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99548456; called by muse, mutect2, varscan2
- CLCN2 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs184790106, COSV99658871; called by muse, mutect2, varscan2
- CLDN18 | c.211G>A p.G71R | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV99480920; called by muse, mutect2, varscan2
- CLEC4F | c.1098G>A p.M366I | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV99713928; called by muse, mutect2, varscan2
- CLEC4F | c.994C>T p.H332Y | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as rs782507105, COSV55479102; called by muse, mutect2, varscan2
- CLIC2 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.59); catalogued as COSV100425702; called by muse, mutect2, varscan2
- CLIC6 | c.1477C>T p.L493F (on ENST00000360731 / NM_001317009.2; = p.L475F on NM_053277.3) | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100659291; called by muse, mutect2, varscan2
- CLIP2 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1554732781, COSV99792002; called by muse, mutect2
- CNBD1 | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775205356, COSV101582292; called by muse, mutect2, varscan2
- CNTN4 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1018920181, COSV61867465; called by muse, mutect2, varscan2
- CNTN5 | c.3160G>A p.G1054R | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866244785, COSV54341831; called by muse, mutect2, varscan2
- CNTN6 | c.2039G>A p.S680N | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as COSV100611529, COSV100611859; called by muse, mutect2, varscan2
- COCH | c.1747G>A p.E583K (on ENST00000216361 / NM_001347720.1; = p.E518K on NM_004086.3) | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.64); catalogued as rs1168893973, COSV99363849; called by muse, mutect2, varscan2
- COG4 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100092113; called by muse, mutect2, varscan2
- COL11A1 | c.1967C>T p.P656L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV100617761; called by muse, mutect2, varscan2
- COL11A1 | c.1643C>T p.S548L | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.067); catalogued as COSV62178371, COSV62180680; called by muse, mutect2, varscan2
- COL14A1 | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.137); catalogued as COSV52855312, COSV99920156; called by muse, mutect2, varscan2
- COL16A1 | c.2764G>A p.G922R | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as COSV99595127; called by muse, mutect2, varscan2
- COL17A1 | c.1750C>T p.R584* | Nonsense Mutation (SNP) | VAF 7/15 reads (47%) | catalogued as rs894978176, COSV62226247; called by muse, mutect2
- COL19A1 | c.2606G>A p.G869E | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100506485, COSV59589417; called by muse, mutect2, varscan2
- COL1A2 | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV99800582, COSV99800638; called by muse, mutect2
- COL21A1 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99779643; called by muse, mutect2, varscan2
- COL2A1 | c.3232C>T p.P1078S | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs1565670143, COSV100477160; called by muse, mutect2, varscan2
- COL3A1 | c.2765C>T p.P922L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100483544; called by muse, mutect2, varscan2
- COL4A3 | c.2596G>A p.E866K | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.031); catalogued as COSV101170474; called by muse, mutect2, varscan2
- COL4A3 | c.3238G>A p.G1080R | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1267839034, CM1414100, COSV100516822; called by muse, mutect2, varscan2
- COL4A4 | c.1934G>A p.G645E | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100307432; called by muse, mutect2, varscan2
- COL4A5 | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.86); PolyPhen benign (0.031); catalogued as COSV60366150; called by muse, varscan2
- COL4A5 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.038); catalogued as rs1186225656, COSV100089026; called by muse, varscan2
- COL4A5 | c.2192G>A p.G731E | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100089028; called by muse, mutect2, varscan2
- COL4A6 | c.4886G>A p.R1629Q | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1302611212, COSV100564777; called by muse, mutect2
- COL4A6 | c.4458G>A p.M1486I | Missense Mutation (SNP) | VAF 51/174 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100564779; called by muse, mutect2, varscan2
- COL5A2 | c.1354C>T p.P452S | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.081); catalogued as COSV100880637; called by mutect2, varscan2
- COL5A3 | c.3581G>A p.G1194E | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as COSV99319463; called by muse, mutect2, varscan2
- COL5A3 | c.2884G>A p.G962R | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99319466; called by muse, mutect2, varscan2
- COL5A3 | c.1843C>T p.R615C | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.353); catalogued as rs764030577, COSV53406593; called by muse, mutect2, varscan2
- COL6A3 | c.4270C>T p.R1424C | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.17); catalogued as rs768522226, COSV99798394; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL7A1 | c.7447G>A p.D2483N | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV100097149; called by muse, mutect2, varscan2
- COL7A1 | c.7381G>A p.G2461R | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM167156, COSV100097154; called by muse, mutect2, varscan2
- COL9A3 | c.1784G>A p.R595K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (1); PolyPhen probably damaging (0.992); catalogued as COSV58983421; called by muse, mutect2
- CORIN | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 29/74 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV99904174; called by muse, mutect2, varscan2
- CPA6 | c.911A>T p.K304M | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99914302; called by muse, mutect2, varscan2
- CPN2 | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs751515015, COSV60470004; called by muse, mutect2, varscan2
- CPT1C | c.2111C>T p.S704F | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99773583; called by muse, mutect2, varscan2
- CR2 | c.1646G>A p.G549E | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65510190; called by muse, mutect2
- CREBBP | c.6236C>T p.S2079F | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99271139; called by muse, mutect2, varscan2
- CREBBP | c.4155G>T p.M1385I | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV99271142; called by muse, mutect2, varscan2
- CRTC2 | c.836C>T p.T279I | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV100339280; called by muse, mutect2, varscan2
- CSF2RB | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.095); catalogued as rs1473071183, COSV99454260; called by muse, mutect2, varscan2
- CSMD2 | c.7714G>A p.E2572K | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.464); catalogued as COSV53911635; called by muse, mutect2, varscan2
- CSMD2 | c.2605G>A p.D869N | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99593445; called by muse, mutect2, varscan2
- CSMD3 | c.9710C>T p.P3237L (on ENST00000297405 / NM_001363185.1; = p.P3068L on NM_052900.3) | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.964); catalogued as COSV99842913; called by muse, mutect2, varscan2
- CTAGE1 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV101194634, COSV101194635; called by muse, mutect2, varscan2
- CTC1 | c.826C>T p.R276W | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs267605102, COSV100236666; called by muse, mutect2, varscan2
- CTIF | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.536); catalogued as COSV99838189; called by muse, mutect2, varscan2
- CTNNA3 | c.2086G>A p.D696N | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV101041524, COSV101041608; called by muse, mutect2, varscan2
- CTNNA3 | c.322T>C p.F108L | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100373710; called by muse, mutect2, varscan2
- CTTNBP2 | c.1519C>T p.P507S | Missense Mutation (SNP) | VAF 34/159 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99354564; called by muse, mutect2, varscan2
- CUBN | c.8428C>T p.H2810Y | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV64728320; called by muse, mutect2, varscan2
- CUBN | c.8321C>T p.S2774L | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100913246; called by muse, mutect2, varscan2
- CUBN | c.404T>G p.V135G | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.127); catalogued as COSV100910639; called by muse, mutect2, varscan2
- CUL5 | c.1637C>T p.S546L | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101263729; called by muse, mutect2, varscan2
- CUL9 | c.1411C>T p.P471S | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as COSV52726008; called by muse, mutect2, varscan2
- CUX2 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99920362; called by muse, mutect2, varscan2
- CX3CL1 | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.052); catalogued as rs371635469, COSV50056755; called by muse, mutect2, varscan2
- CXorf21 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as COSV100973340; called by muse, mutect2, varscan2
- CYP19A1 | c.1470G>A p.M490I | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as COSV53058702; called by muse, mutect2, varscan2
- CYP2B6 | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs141530852; called by muse, mutect2, varscan2
- CYP2C18 | c.1370A>C p.N457T | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99608790; called by muse, mutect2
- CYP2C8 | c.271G>A p.G91R | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.625); catalogued as COSV100987989; called by muse, mutect2
- CYP4A22 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.219); catalogued as COSV99595250; called by muse, mutect2, varscan2
- CYP4X1 | c.1451C>T p.P484L | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.261); catalogued as rs377650246; called by muse, mutect2, varscan2
- CYP4Z1 | c.1034G>A p.R345K | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.813); catalogued as rs267598632, COSV100497854; called by muse, mutect2, varscan2
- CYP4Z1 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.038); catalogued as COSV100497855, COSV100497985; called by muse, mutect2, varscan2
- CYP8B1 | c.1216G>A p.D406N | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.078); catalogued as COSV60226997; called by muse, mutect2, varscan2
- DAB1 | c.1051C>T p.Q351* (on ENST00000371231; = p.Q318* on NM_021080.5 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 7/48 reads (15%) | catalogued as COSV100976498; called by muse, mutect2, varscan2
- DACH1 | c.1295C>T p.P432L (on ENST00000619232 / NM_001366712.1; = p.P380L on NM_080759.6) | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100498967; called by muse, mutect2
- DBP | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99709501; called by muse, mutect2, varscan2
- DCC | c.1098G>T p.K366N | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100502046; called by muse, mutect2, varscan2
- DCC | c.2923G>A p.G975R | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59138445; called by muse, mutect2, varscan2
- DCC | c.4330G>A p.G1444S | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.224); catalogued as COSV101473428; called by muse, mutect2, varscan2
- DCP1B | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV54967766; called by muse, mutect2, varscan2
- DDI1 | c.754G>A p.G252R | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56370423; called by muse, mutect2, varscan2
- DDX31 | c.2158C>T p.Q720* | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as rs981948722, COSV100936851; called by muse, mutect2
- DEFA4 | c.118C>T p.Q40* | Nonsense Mutation (SNP) | VAF 10/59 reads (17%) | catalogued as COSV52404480; called by muse, mutect2, varscan2
- DENND3 | c.3023G>A p.S1008N | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99371431; called by muse, mutect2, varscan2
- DES | c.1027G>A p.D343N | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as rs763903197, COSV64660678; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DEUP1 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99976900; called by muse, mutect2, varscan2
- DGAT2L6 | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as rs964106608, COSV100284101; called by muse, mutect2, varscan2
- DGKG | c.1810G>A p.E604K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99403103, COSV99404053; called by muse, mutect2
- DGKZ | c.2581C>T p.P861S (on ENST00000454345 / NM_001105540.2; = p.P673S on NM_003646.4) | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as COSV100551816; called by muse, mutect2, varscan2
- DHH | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.253); catalogued as COSV99908900; called by muse, mutect2, varscan2
- DIAPH2 | c.2666G>A p.R889Q | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs145712757, COSV100234440, COSV61289154; called by muse, mutect2, varscan2
- DISP1 | c.3529C>T p.H1177Y | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.04); catalogued as COSV99451777; called by muse, mutect2, varscan2
- DLX6 | c.672A>T p.K224N | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99142458; called by muse, mutect2, varscan2
- DMBT1 | c.7160C>T p.S2387F (on ENST00000338354 / NM_001377530.1; = p.S1630F on NM_004406.3) | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV57535809, COSV57541035; called by muse, mutect2, varscan2
- DMGDH | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as rs765873369, COSV99669041; called by muse, mutect2
- DNAAF5 | c.1025-1G>A p.X342_splice | Splice Site (SNP) | VAF 30/145 reads (21%) | catalogued as rs1204540440, COSV99860148; called by muse, mutect2, varscan2
- DNAH10 | c.5524G>A p.D1842N (on ENST00000409039; = p.D1781N on NM_207437.3) | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.828); catalogued as COSV68999029; called by muse, mutect2, varscan2
- DNAH11 | c.10504G>A p.G3502R | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100180143; called by muse, mutect2, varscan2
- DNAH3 | c.10168G>A p.E3390K | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.285); catalogued as COSV54505260, COSV99768584; called by muse, mutect2, varscan2
- DNAH3 | c.3614G>A p.G1205E | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99769521; called by muse, mutect2, varscan2
- DNAH5 | c.13807C>T p.L4603F | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.859); catalogued as rs191662365, COSV54226149; called by muse, mutect2, varscan2
- DNAH5 | c.13546G>A p.E4516K | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.314); catalogued as rs866204172, COSV99451576; called by muse, mutect2, varscan2
- DNAH5 | c.7839G>A p.M2613I | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs1486813109, COSV54201446; called by muse, mutect2, varscan2
- DNAH5 | c.3397G>A p.E1133K | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV99452477; called by muse, mutect2, varscan2
- DNAH5 | c.2065C>T p.H689Y | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as COSV54229374; called by muse, mutect2, varscan2
- DNAH7 | c.10006G>A p.D3336N | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as rs972410127, COSV100416648; called by muse, mutect2, varscan2
- DNAH7 | c.9906G>A p.W3302* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | catalogued as COSV100416651; called by muse, mutect2, varscan2
- DNAH7 | c.4006G>A p.E1336K | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56759570; called by muse, mutect2, varscan2
- DNAH7 | c.3361G>A p.E1121K | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs372668189; called by muse, mutect2, varscan2
- DNAH8 | c.6058G>A p.G2020R | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100546656; called by muse, mutect2, varscan2
- DNAH8 | c.10453G>C p.E3485Q | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as COSV100546658, COSV59431405; called by muse, mutect2, varscan2
- DNAI1 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs775237348, COSV99647040; called by muse, mutect2, varscan2
- DNMT3A | c.467C>T p.T156I | Missense Mutation (SNP) | VAF 51/236 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.19); catalogued as COSV99263748; called by muse, mutect2, varscan2
- DNTT | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as COSV64524018; called by muse, mutect2, varscan2
- DOCK5 | c.2240C>A p.S747Y | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as COSV99377448; called by muse, mutect2, varscan2
- DPPA3 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.162); catalogued as rs1476085353, COSV61502941; called by muse, mutect2, varscan2
- DPPA4 | c.739C>T p.H247Y | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.569); catalogued as COSV100169409; called by muse, mutect2, varscan2
- DQX1 | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 51/198 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs749983331, COSV66353228; called by muse, mutect2, varscan2
- DRAXIN | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.275); catalogued as COSV99610887; called by muse, mutect2, varscan2
- DSC2 | c.1820C>T p.P607L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99199776; called by muse, mutect2, varscan2
- DSC2 | c.712G>A p.D238N | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV51867726; called by muse, mutect2, varscan2
- DSCAM | c.1016G>A p.G339E | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV68031995; called by muse, mutect2
- DSG1 | c.2073G>A p.M691I | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV57134869; called by muse, mutect2, varscan2
- DSG4 | c.2680A>T p.M894L | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV100356248; called by muse, mutect2, varscan2
- DUOX2 | c.4510G>C p.E1504Q | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV101199853; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1367C>T p.S456L | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.074); catalogued as rs769670477, COSV50050996; called by muse, mutect2, varscan2
- DUSP21 | c.383C>T p.S128L | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV59133908; called by muse, mutect2, varscan2
- DUSP4 | c.780G>A p.M260I | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99529984; called by muse, mutect2, varscan2
- DYNC1H1 | c.8165C>T p.P2722L | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100795195; called by muse, mutect2, varscan2
- DYNLL2 | c.223T>C p.Y75H | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.443); catalogued as COSV101651065; called by muse, mutect2, varscan2
- DYRK4 | c.295C>T p.H99Y | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV50541235; called by muse, mutect2, varscan2
- DYSF | c.2783G>A p.G928E | Missense Mutation (SNP) | VAF 81/333 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99249595; called by muse, mutect2, varscan2
- EEPD1 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99632778; called by muse, mutect2, varscan2
- EFCAB5 | c.1055C>T p.S352L | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as COSV100300580; called by muse, mutect2, varscan2
- EFCAB6 | c.2011G>A p.D671N | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.086); catalogued as rs748318259, COSV53074728; called by muse, mutect2, varscan2
- EFHB | c.2390G>A p.W797* | Nonsense Mutation (SNP) | VAF 28/94 reads (30%) | catalogued as COSV99859461, COSV99860046; called by muse, mutect2, varscan2
- EGFLAM | c.368G>A p.G123E | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100471882; called by muse, mutect2, varscan2
- EGR3 | c.1066C>T p.L356F | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1205126454, COSV100416245; called by muse, mutect2, varscan2
- EIF3D | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs771870770, COSV53402599; called by muse, mutect2, varscan2
- ELMO1 | c.22G>A p.V8I | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.132); catalogued as COSV60316446; called by muse, mutect2, varscan2
- ELOA2 | c.1806A>T p.K602N | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as COSV99797490; called by muse, mutect2, varscan2
- EMILIN3 | c.323T>C p.V108A | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as rs766348606, COSV100182736; called by muse, mutect2, varscan2
- ENDOD1 | c.1246C>T p.L416F | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.946); catalogued as rs771252357, COSV99566715; called by muse, mutect2, varscan2
- ENPP7 | c.599C>T p.S200F | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.132); catalogued as COSV100093608; called by muse, mutect2, varscan2
- ENTPD3 | c.584G>A p.G195E | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV100088932; called by muse, mutect2, varscan2
- EPB41 | c.1609A>G p.K537E (on ENST00000343067 / NM_001166005.2; = p.K328E on NM_004437.4) | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100549220; called by muse, mutect2, varscan2
- EPB41L4B | c.2014C>T p.R672* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as rs921541583, COSV100775848, COSV63124104; called by muse, mutect2, varscan2
- EPHA3 | c.654G>A p.M218I | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as rs770106113, COSV100347492; called by muse, mutect2, varscan2
- EPHA6 | c.1057C>T p.P353S | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV67559487; called by muse, mutect2
- EPHB2 | c.1726G>A p.E576K (on ENST00000400191 / NM_001309193.2; = p.E577K on NM_004442.7) | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.147); catalogued as COSV101007296; called by muse, mutect2, varscan2
- ERC2 | c.718C>T p.H240Y | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as COSV55603408; called by muse, mutect2
- ERCC4 | c.2543C>T p.P848L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.964); catalogued as COSV100319039; called by muse, mutect2, varscan2
- ERICH3 | c.4312G>A p.E1438K | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as COSV58602765; called by muse, mutect2, varscan2
- ERICH3 | c.2624C>T p.A875V | Missense Mutation (SNP) | VAF 56/179 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.077); catalogued as rs751330822, COSV100445201, COSV58603119; called by muse, mutect2, varscan2
- ERP27 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.01); catalogued as COSV99844406; called by muse, mutect2, varscan2
- ERRFI1 | c.1370C>T p.S457F | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as rs1373015775, COSV101088216; called by muse, mutect2, varscan2
- ESPN | c.1013C>T p.S338F | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1202576065, COSV64704591; called by muse, mutect2, varscan2
- ESR2 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.226); catalogued as COSV99963652; called by muse, mutect2, varscan2
- ETNPPL | c.912G>A p.M304I | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as COSV99625544; called by muse, mutect2
- EXT2 | c.1486C>T p.P496S (on ENST00000343631; = p.P529S on NM_000401.3) | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100640661; called by muse, mutect2, varscan2
- EYS | c.1058A>C p.D353A | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.185); catalogued as rs1387587935, COSV100676953, COSV100677288; called by muse, mutect2, varscan2
- EZHIP | c.1255C>T p.L419F | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.31); catalogued as rs782069309, COSV100539825; called by muse, mutect2, varscan2
- F8 | c.4169C>T p.S1390L | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.15); catalogued as CM1212735, COSV100811739; called by muse, mutect2, varscan2
- F8 | c.1745G>A p.G582E | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM062668, CM070104, CM145558, COSV64273953; called by muse, mutect2, varscan2
- FAM181A | c.395G>A p.R132K | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1466558185, COSV99967956; called by muse, mutect2, varscan2
- FAM47A | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs267606442, COSV100650012, COSV60496789; called by muse, mutect2, varscan2
- FAM83B | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV60920165; called by muse, mutect2, varscan2
- FANK1 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV64156739; called by muse, mutect2, varscan2
- FASLG | c.31C>T p.Q11* | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | catalogued as COSV100390574; called by muse, mutect2, varscan2
- FASLG | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100390575; called by muse, mutect2, varscan2
- FAT1 | c.12845C>T p.P4282L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV101499548, COSV101499695; called by muse, mutect2, varscan2
- FAT1 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.744); catalogued as rs771355532, COSV101499550; called by muse, mutect2, varscan2
- FAT3 | c.2009C>T p.S670L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53092495, COSV53093860; called by muse, mutect2, varscan2
- FAT3 | c.7714G>T p.V2572L | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV99968807; called by muse, mutect2, varscan2
- FAT4 | c.7193T>G p.V2398G | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.791); catalogued as COSV58707747; called by muse, mutect2, varscan2
- FAT4 | c.8122G>A p.E2708K | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.106); catalogued as rs865926471, COSV100629593; called by muse, mutect2, varscan2
- FBF1 | c.988C>T p.P330S (on ENST00000586717; = p.P344S on NM_001319193.1) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.419); catalogued as COSV100045463; called by muse, mutect2, varscan2
- FBLIM1 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs768724528, COSV60030768; called by muse, mutect2, varscan2
- FBLN5 | c.404C>T p.S135F | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.799); catalogued as COSV50902019; called by muse, mutect2, varscan2
- FBN2 | c.1205C>T p.P402L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.812); catalogued as COSV99329631; called by muse, mutect2, varscan2
- FBXW10 | c.2366G>A p.G789E | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1360016881, COSV100111658; called by muse, mutect2
- FCRL5 | c.1972C>T p.R658C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.479); catalogued as rs1243936761, COSV62511728; called by muse, mutect2, varscan2
- FCRL5 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.91); PolyPhen benign (0.013); catalogued as rs1406891065, COSV62512447, COSV62513927; called by muse, mutect2, varscan2
- FCRLA | c.755C>T p.T252I (on ENST00000367959; = p.T229I on NM_032738.4) | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as COSV99375634; called by muse, mutect2, varscan2
- FER1L5 | c.4984G>C p.G1662R (on ENST00000623019; = p.G1635R on NM_001293083.2) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV101208893; called by muse, mutect2, varscan2
- FGA | c.1312G>A p.G438R | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100120594; called by muse, varscan2
- FGD2 | c.556A>C p.I186L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.054); catalogued as COSV99236481; called by muse, mutect2, varscan2
- FGFR3 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.248); catalogued as COSV99603026; called by muse, mutect2, varscan2
- FHIT | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs1373513716, COSV59329887; called by muse, mutect2, varscan2
- FHL1 | c.178T>C p.F60L | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as COSV100600823; called by muse, mutect2, varscan2
- FLG | c.8188G>A p.E2730K | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.431); catalogued as rs1224614934, COSV100911923; called by mutect2, varscan2
- FLG2 | c.869G>A p.R290K | Missense Mutation (SNP) | VAF 25/218 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs759360804, COSV101166078; called by muse, mutect2, varscan2
- FLNB | c.6278G>A p.G2093E | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs967804303, COSV99914183; called by muse, mutect2
- FLNB | c.6658G>A p.E2220K | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); catalogued as COSV99914188; called by muse, mutect2, varscan2
- FLOT1 | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99458309; called by muse, mutect2, varscan2
- FLT3 | c.385G>A p.V129I | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99609757; called by muse, mutect2, varscan2
- FMR1 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV54423104; called by muse, mutect2, varscan2
- FNBP4 | c.2171C>T p.P724L | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as rs373416629; called by muse, mutect2, varscan2
- FNDC7 | c.1233G>A p.M411I | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99601544; called by muse, mutect2, varscan2
- FOLR1 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.068); catalogued as COSV100398573, COSV56617235; called by muse, mutect2, varscan2
- FOXP2 | c.2023G>A p.E675K | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV63482671; called by muse, mutect2, varscan2
- FOXS1 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99640110; called by muse, mutect2, varscan2
- FRMPD4 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.416); catalogued as COSV101043701; called by muse, varscan2
- FRMPD4 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV101043702; called by muse, varscan2
- FRYL | c.943C>T p.P315S | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51950872; called by muse, mutect2, varscan2
- FSIP2 | c.17210C>A p.S5737* | Nonsense Mutation (SNP) | VAF 6/53 reads (11%) | catalogued as COSV100553536, COSV100555890; called by muse, mutect2, varscan2
- FSTL5 | c.787G>A p.G263R | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1241569564, COSV100059307; called by muse, mutect2, varscan2
- FUT9 | c.368A>G p.Q123R | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.326); catalogued as COSV100134057; called by muse, mutect2, varscan2
- GAB4 | c.1339T>A p.S447T | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.077); catalogued as COSV101272058; called by muse, mutect2, varscan2
- GAB4 | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV101272059; called by muse, mutect2, varscan2
- GABRA1 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.011); catalogued as COSV99196158; called by muse, mutect2, varscan2
- GABRA3 | c.1241C>T p.S414F | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.503); catalogued as rs868775494, COSV64795226; called by muse, mutect2, varscan2
- GABRD | c.899C>T p.S300F | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101059564; called by muse, mutect2, varscan2
- GAK | c.1892C>T p.P631L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100033934; called by muse, mutect2, varscan2
- GALNT8 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV52897124; called by muse, varscan2
- GAPVD1 | c.994C>T p.P332S | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99783573; called by mutect2, varscan2
- GAPVD1 | c.2570C>T p.P857L (on ENST00000394104; = p.P884L on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs779567360, COSV99783578; called by muse, mutect2, varscan2
- GASK1B | c.1195G>A p.G399R | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.934); catalogued as COSV99647983; called by muse, mutect2, varscan2
- GBA3 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV72438787; called by muse, mutect2, varscan2
- GCNT2 | c.763C>T p.P255S | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs777630944, COSV101097574; called by muse, mutect2, varscan2
- GDAP1 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as COSV99619764; called by muse, mutect2, varscan2
- GDF3 | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as rs376200767; called by muse, mutect2, varscan2
- GDI1 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 59/404 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.144); catalogued as COSV99341136; called by muse, mutect2, varscan2
- GDPD4 | c.1389+1G>A p.X463_splice | Splice Site (SNP) | VAF 12/38 reads (32%) | catalogued as COSV100265531; called by muse, mutect2, varscan2
- GEM | c.103A>G p.K35E | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1563608593, COSV99891544; called by muse, mutect2, varscan2
- GGA1 | c.1351C>T p.P451S | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100289834; called by muse, mutect2
- GGCX | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs758978640, COSV99290118; called by muse, mutect2, varscan2
- GJB6 | c.700C>T p.H234Y | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.67); PolyPhen benign (0.052); catalogued as COSV99576123; called by muse, mutect2, varscan2
- GLB1L3 | c.1229C>A p.P410H | Missense Mutation (SNP) | VAF 78/293 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as rs777482420, COSV101345141, COSV101345152; called by muse, mutect2, varscan2
- GLDN | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 45/178 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.051); catalogued as rs758517964, COSV100117960; called by muse, mutect2, varscan2
- GLI2 | c.1594G>A p.D532N (on ENST00000361492 / NM_001374353.1; = p.D549N on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV100083996; called by muse, mutect2, varscan2
- GLIPR1 | c.296A>G p.N99S | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99875810; called by muse, mutect2, varscan2
- GPR108 | c.746C>T p.P249L (on ENST00000264080 / NM_001080452.1; = p.P7L on NM_020171.2) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as COSV99901420; called by muse, mutect2, varscan2
- GPR15 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.551); catalogued as rs765197769, COSV99423910; called by muse, mutect2, varscan2
- GPRASP1 | c.2805G>A p.M935I | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs781515375, COSV100851054; called by muse, mutect2, varscan2
- GPRASP2 | c.1666C>T p.Q556* | Nonsense Mutation (SNP) | VAF 24/92 reads (26%) | catalogued as COSV100176890; called by muse, mutect2, varscan2
- GPRC6A | c.2227G>A p.E743K | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV100114627; called by muse, mutect2, varscan2
- GREB1 | c.2512C>T p.P838S | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.766); catalogued as COSV99303469; called by muse, mutect2
- GREB1 | c.5393C>T p.A1798V | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as COSV99303474; called by muse, mutect2, varscan2
- GRIA1 | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs377273074; called by muse, mutect2, varscan2
- GRIA1 | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV99601450; called by muse, mutect2, varscan2
- GRIA1 | c.2116C>T p.R706* | Nonsense Mutation (SNP) | VAF 13/70 reads (19%) | catalogued as COSV53625087; called by muse, mutect2, varscan2
- GRIA4 | c.1013C>A p.P338Q | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV56905223, COSV99233559; called by muse, mutect2, varscan2
- GRID2 | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.989); catalogued as rs759811681, COSV99944677; called by muse, varscan2
- GRID2 | c.1034G>A p.R345Q | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1383722822, COSV56249117; called by muse, mutect2, varscan2
- GRIN2A | c.1315T>A p.F439I | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs755045335, COSV100410637; called by muse, mutect2, varscan2
- GRIN2A | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.079); catalogued as rs774932381, COSV58021477; called by muse, mutect2, varscan2
- GRIN2A | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.529); catalogued as COSV58057122; called by muse, mutect2, varscan2
- GRIN2B | c.3220G>A p.E1074K | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV74205994; called by muse, mutect2, varscan2
- GRIN2B | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.552); catalogued as rs747880300, COSV74204723; called by muse, mutect2, varscan2
- GRIN2D | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV99616791; called by muse, mutect2, varscan2
- GRIN3B | c.2036G>A p.G679E | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99312780; called by muse, mutect2
- GRM8 | c.2510A>G p.K837R | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs766834766, COSV100284994; called by muse, mutect2, varscan2
- GTF2IRD1 | c.1279T>C p.F427L | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.96); catalogued as COSV99735146; called by muse, mutect2, varscan2
- GTF2IRD1 | c.1991C>T p.S664F | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.36); catalogued as rs782209153, COSV99735147; called by muse, mutect2, varscan2
- GTF3C1 | c.5537C>T p.P1846L | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.058); catalogued as COSV62240621; called by muse, mutect2, varscan2
- GTPBP4 | c.1150C>A p.R384S | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV100672884; called by muse, mutect2, varscan2
- GUCY1A2 | c.1822G>A p.G608R | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV56507617; called by muse, mutect2
- GUCY2C | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.744); catalogued as rs1057520084, COSV99663992; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GUCY2D | c.2719G>A p.D907N | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); catalogued as rs1314298060, COSV54697433; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GUCY2F | c.1943C>T p.S648L | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.173); catalogued as COSV99485443; called by muse, mutect2, varscan2
- GYPB | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.671); catalogued as rs374629471; called by muse, mutect2, varscan2
- H1-4 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.043); catalogued as rs1443547361; called by muse, mutect2, varscan2
- H3C2 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 48/198 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.045); catalogued as COSV99451651; called by muse, mutect2, varscan2
- HACE1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.664); catalogued as COSV99494120; called by muse, mutect2, varscan2
- HADH | c.676T>C p.Y226H | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs146036912, CM064046; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- HARS2 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100047793; called by muse, mutect2, varscan2
- HCLS1 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.85); PolyPhen benign (0.029); catalogued as rs371572740; called by mutect2, varscan2
- HEATR1 | c.4234C>T p.L1412F | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100857743; called by muse, mutect2, varscan2
- HEATR6 | c.2822C>T p.P941L | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.766); catalogued as rs766891804, COSV99482514; called by muse, mutect2, varscan2
- HECTD3 | c.575C>T p.S192L | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.019); catalogued as rs974477458, COSV99870372; called by muse, mutect2, varscan2
- HECTD4 | c.10384C>T p.P3462S | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV101108183; called by muse, mutect2, varscan2
- HELQ | c.3127C>T p.P1043S | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.474); catalogued as rs1461527697, COSV55028032, COSV99787994; called by muse, mutect2, varscan2
- HERC2 | c.11497C>T p.P3833S | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.205); catalogued as rs781750476, COSV99875822; called by muse, mutect2
- HFM1 | c.3647C>T p.P1216L | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV99646508; called by muse, mutect2, varscan2
- HFM1 | c.2521C>T p.R841W | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs775049733, COSV54036432; called by muse, mutect2, varscan2
- HIRIP3 | c.160G>A p.V54M | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.284); catalogued as rs1367422801, COSV99663243; called by muse, mutect2, varscan2
- HIVEP1 | c.6908C>T p.S2303F | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65103182; called by muse, mutect2, varscan2
- HIVEP3 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.707); catalogued as rs149979631, COSV99912468; called by muse, mutect2, varscan2
- HLCS | c.1274C>T p.S425F | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs143463463, COSV100358467; called by muse, mutect2, varscan2
- HMCN1 | c.9418G>A p.D3140N | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as COSV99633522; called by muse, mutect2, varscan2
- HMCN1 | c.14840G>A p.G4947D | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99633527; called by muse, mutect2, varscan2
- HNF4G | c.593G>A p.G198E (on ENST00000354370 / NM_001330561.2; = p.G245E on NM_004133.5) | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV62965564; called by muse, mutect2, varscan2
- HOMER2 | c.98C>T p.T33I | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV100420482; called by muse, mutect2, varscan2
- HPCAL1 | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100324162; called by muse, mutect2, varscan2
- HPCAL1 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1558537435, COSV100324165; called by muse, mutect2, varscan2
- HSFX1 | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs1439779364; called by muse, mutect2, varscan2
- HSPA4L | c.1840G>A p.E614K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV99613475; called by muse, mutect2, varscan2
- HTATSF1 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as COSV99511837; called by muse, mutect2, varscan2
- HTN3 | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as COSV101126186; called by muse, mutect2, varscan2
- HTN3 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs1187095444, COSV101126187; called by muse, mutect2, varscan2
- HUWE1 | c.11725G>A p.A3909T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.068); catalogued as COSV99470130; called by muse, mutect2
- HUWE1 | c.9128G>A p.R3043Q | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as rs149673252, COSV99473575; called by muse, mutect2, varscan2
- HYDIN | c.650C>T p.T217I | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs868103666, COSV99864377; called by mutect2, varscan2
- IBA57 | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as COSV100812788; called by muse, mutect2, varscan2
- IGDCC3 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs751367900, COSV60078430; called by muse, mutect2, varscan2
- IGF2BP1 | c.1354C>T p.R452C | Missense Mutation (SNP) | VAF 84/176 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as rs867424326, COSV51729521, COSV51730080; called by muse, mutect2, varscan2
- IGHV1-46 | c.263C>T p.T88I | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.231); catalogued as rs1555524715; called by muse, mutect2, varscan2
- IGSF1 | c.2624C>T p.P875L | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100812227; called by muse, mutect2, varscan2
- IGSF1 | c.2584G>A p.D862N | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs772636261, COSV63839685; called by muse, mutect2, varscan2
- IKZF1 | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); catalogued as COSV58790913; called by muse, mutect2
- IL1R1 | c.435G>A p.M145I | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99292794; called by muse, mutect2
- IL1RAPL2 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV61154691; called by muse, mutect2, varscan2
- IL1RL2 | c.61G>A p.G21R | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.05); catalogued as COSV99960989; called by muse, mutect2, varscan2
- IL1RN | c.350G>A p.R117K (on ENST00000409930 / NM_173842.3; = p.R99K on NM_000577.5) | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99381752; called by muse, mutect2, varscan2
- IL22RA1 | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1307905140, COSV99583200; called by muse, mutect2, varscan2
- IL36B | c.379G>A p.G127R | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.006); catalogued as COSV99382990; called by muse, mutect2
- IL37 | c.51G>A p.W17* | Nonsense Mutation (SNP) | VAF 12/62 reads (19%) | catalogued as rs1278412595, COSV99636397; called by muse, mutect2, varscan2
- IL37 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.587); catalogued as rs145730208, COSV54492103; called by muse, mutect2, varscan2
- INO80 | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866583951, COSV100731638; called by muse, mutect2, varscan2
- INPPL1 | c.3256C>T p.R1086C | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as rs200480750, COSV53359274; called by muse, mutect2, varscan2
- IPO4 | c.883C>T p.L295F | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1464823661, COSV99938191; called by muse, mutect2, varscan2
- IPO9 | c.2944G>A p.D982N | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.737); catalogued as rs761596816, COSV100843523; called by muse, mutect2, varscan2
- IQUB | c.533-1G>A p.X178_splice | Splice Site (SNP) | VAF 16/84 reads (19%) | catalogued as COSV100227267; called by muse, mutect2, varscan2
- ITGA2 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.14); catalogued as COSV99671316; called by muse, mutect2, varscan2
- ITGA4 | c.2680G>A p.D894N | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV101223569; called by muse, mutect2, varscan2
- ITGA8 | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.913); catalogued as COSV100959558, COSV65223898; called by muse, mutect2
- ITGA8 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.461); catalogued as COSV65223985; called by muse, mutect2, varscan2
- ITGAL | c.2828G>A p.G943D | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.225); catalogued as rs1324005870, COSV100776316; called by muse, mutect2, varscan2
- ITGB6 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.794); catalogued as COSV99324832; called by muse, mutect2, varscan2
- ITPKB | c.2495C>A p.T832K | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV55263567, COSV99684904; called by muse, mutect2, varscan2
- ITPRIP | c.404C>T p.T135I | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV53393385; called by muse, mutect2, varscan2
- IVNS1ABP | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.557); catalogued as rs1248093961, COSV100832557; called by muse, mutect2, varscan2
- IZUMO1R | c.317G>A p.W106* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as COSV60622091; called by muse, mutect2, varscan2
- JAG1 | c.434C>T p.T145I | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV54754318, COSV54756473, COSV99653320; called by muse, mutect2, varscan2
- JAKMIP2 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 64/192 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV54609259; called by muse, mutect2, varscan2
- JARID2 | c.1573C>T p.R525C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); catalogued as rs373104387; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.323C>T p.P108L | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.41); catalogued as rs1318639513, COSV100584120; called by muse, mutect2, varscan2
- JPH3 | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1264044529, COSV52463898; called by muse, mutect2, varscan2
- KCNA10 | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV100871469; called by muse, mutect2, varscan2
- KCNB2 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV73049978; called by muse, mutect2, varscan2
- KCNB2 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV73050969, COSV73051132; called by muse, mutect2, varscan2
- KCNB2 | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.627); catalogued as rs1163367178, COSV73050155; called by muse, mutect2, varscan2
- KCNB2 | c.2390C>T p.S797F | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.445); catalogued as COSV73049826; called by muse, mutect2, varscan2
- KCNC1 | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.051); catalogued as COSV99789567; called by muse, mutect2, varscan2
- KCNH2 | c.2606C>T p.P869L | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.31); catalogued as rs763031434, COSV100060723; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNH5 | c.1654C>T p.R552* | Nonsense Mutation (SNP) | VAF 10/54 reads (19%) | catalogued as rs868309881, COSV59752841; called by muse, mutect2, varscan2
- KCNH7 | c.380T>A p.I127N | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV100033304, COSV100037182; called by muse, mutect2, varscan2
- KCNH8 | c.1234T>G p.L412V | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as COSV100110732; called by muse, mutect2, varscan2
- KCNIP1 | c.280C>T p.P94S (on ENST00000411494 / NM_001034837.3; = p.P83S on NM_014592.4) | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61085294; called by muse, mutect2, varscan2
- KCNJ3 | c.1349A>T p.K450I | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as COSV99716267; called by muse, mutect2, varscan2
- KCNJ8 | c.1057T>C p.C353R | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99557686; called by muse, mutect2, varscan2
- KCTD19 | c.2131G>T p.G711W | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV100431131; called by muse, mutect2, varscan2
- KCTD19 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs775487609, COSV58574861; called by muse, mutect2, varscan2
- KDM5A | c.2155C>T p.R719C | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1362895739, CM118340, COSV66991075; called by muse, mutect2, varscan2
- KIAA0408 | c.57G>A p.M19I | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV100847012; called by muse, mutect2, varscan2
- KIAA0895 | c.1450G>A p.E484K (on ENST00000297063 / NM_001100425.2; = p.E433K on NM_015314.3) | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.93); catalogued as rs568010970, COSV51709607; called by muse, mutect2, varscan2
- KIAA1109 | c.3306T>A p.H1102Q | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV99169539; called by muse, mutect2, varscan2
- KIAA1109 | c.14020C>T p.R4674C | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1278017597, COSV52663636; called by muse, mutect2, varscan2
- KIAA1217 | c.5668C>T p.P1890S | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.017); catalogued as COSV100287012; called by muse, mutect2, varscan2
- KIAA1549 | c.5812C>T p.L1938F (on ENST00000422774 / NM_001164665.2; = p.L1922F on NM_020910.3) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99651580; called by mutect2, varscan2
- KIAA1755 | c.3257C>T p.S1086F | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV99642434; called by muse, mutect2, varscan2
- KIF1C | c.1450C>T p.R484W | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs571606260, COSV100297273; called by muse, mutect2, varscan2
- KIF21B | c.604C>T p.Q202* | Nonsense Mutation (SNP) | VAF 5/41 reads (12%) | catalogued as COSV100144920; called by muse, mutect2, varscan2
- KIF26A | c.1025G>A p.G342E | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV100181448; called by muse, mutect2
- KIF9 | c.1577C>T p.S526F | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.257); catalogued as COSV99646923; called by muse, mutect2, varscan2
- KL | c.2633G>A p.G878E | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.078); catalogued as COSV101199176; called by muse, mutect2, varscan2
- KLF7 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV100519298, COSV58743839; called by muse, mutect2, varscan2
- KLHL14 | c.1552G>A p.D518N | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.971); catalogued as COSV100839278; called by muse, mutect2, varscan2
- KLK15 | c.116T>C p.L39P | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100032900; called by muse, mutect2, varscan2
- KLRD1 | c.475G>A p.G159R | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.033); catalogued as rs1565474159, COSV100282274; called by muse, mutect2, varscan2
- KMT2B | c.5578T>A p.F1860I | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV99720276; called by muse, mutect2, varscan2
- KMT2B | c.8036G>A p.R2679H | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1452431678, COSV53076657; called by muse, mutect2
- KRT40 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV100898883; called by muse, mutect2, varscan2
- KRT7 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV100081727; called by muse, mutect2, varscan2
- KRTAP10-2 | c.479C>T p.S160F | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.697); catalogued as rs1555918653, COSV100554902; called by muse, mutect2, varscan2
- LAMA2 | c.7889G>A p.R2630Q | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774656522, COSV70346451; called by muse, mutect2, varscan2
- LAMB4 | c.3720A>T p.K1240N | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.081); catalogued as COSV99225059; called by muse, mutect2, varscan2
- LATS2 | c.2432G>T p.G811V | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101231649; called by muse, mutect2, varscan2
- LCTL | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs923663593, COSV100427282; called by muse, mutect2, varscan2
- LDB1 | c.550C>A p.L184M (on ENST00000425280 / NM_001321612.2; = p.L148M on NM_003893.5) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as COSV100756445; called by muse, mutect2, varscan2
- LDLRAD1 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.096); catalogued as COSV100744530; called by muse, mutect2, varscan2
- LDOC1 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.732); catalogued as COSV65159540; called by muse, mutect2, varscan2
- LEPR | c.745G>A p.D249N | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.448); catalogued as COSV60747510, COSV60758963; called by muse, mutect2
- LEPR | c.2558C>T p.S853F | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV100756715; called by muse, mutect2, varscan2
- LGSN | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.255); catalogued as COSV101040631; called by muse, varscan2
- LILRB4 | c.43C>G p.L15V | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.181); catalogued as rs1399311359, COSV99554024, COSV99554123; called by muse, mutect2, varscan2
- LILRB4 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.898); catalogued as COSV54408025, COSV99554026; called by muse, mutect2
- LILRB5 | c.193C>T p.L65F | Missense Mutation (SNP) | VAF 38/177 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs1345341104, COSV60260340; called by muse, mutect2, varscan2
- LIMCH1 | c.371A>T p.K124I | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV100574218; called by muse, mutect2, varscan2
- LIMD1 | c.1598C>A p.S533* | Nonsense Mutation (SNP) | VAF 61/256 reads (24%) | catalogued as COSV99837100; called by muse, mutect2, varscan2
- LIN28B | c.346G>A p.G116R | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs1324609926, COSV61498438; called by muse, mutect2, varscan2
- LMBRD1 | c.1363C>T p.P455S (on ENST00000649011; = p.P433S on NM_018368.4) | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs144636860; called by muse, mutect2, varscan2
- LMTK2 | c.3205C>T p.P1069S | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV51993834; called by muse, mutect2, varscan2
- LMTK3 | c.757G>A p.G253R | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54318563; called by muse, mutect2, varscan2
- LMX1A | c.1145C>T p.S382F | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99672879; called by muse, mutect2, varscan2
- LNX1 | c.1889C>T p.P630L (on ENST00000263925 / NM_001126328.3; = p.P534L on NM_032622.2) | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV99820355; called by muse, mutect2, varscan2
- LPAR1 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as COSV100730976; called by muse, mutect2, varscan2
- LPIN3 | c.1939G>T p.G647C | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100182732; called by muse, mutect2, varscan2
- LPXN | c.1045C>T p.H349Y | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101223095; called by muse, mutect2, varscan2
- LRIG3 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.265); catalogued as COSV100292768; called by muse, mutect2, varscan2
- LRRC32 | c.1861G>A p.G621R | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs781206861, COSV99477170; called by muse, mutect2, varscan2
- LRRC37A3 | c.4058C>T p.S1353F | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.962); catalogued as rs1343965861, COSV100141361; called by muse, mutect2, varscan2
- LRRC8D | c.1516C>T p.P506S | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.035); catalogued as COSV100487459; called by muse, mutect2, varscan2
- LRRFIP1 | c.2048C>T p.T683I (on ENST00000392000 / NM_001137552.2; = p.T659I on NM_004735.4) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.243); catalogued as rs1456446847, COSV99791115; called by muse, mutect2, varscan2
- LRRIQ3 | c.1264G>A p.D422N | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.071); catalogued as COSV100598677; called by muse, mutect2, varscan2
- LRRIQ4 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.185); catalogued as COSV61618911; called by muse, mutect2, varscan2
- LRRK1 | c.2434C>T p.Q812* | Nonsense Mutation (SNP) | VAF 6/53 reads (11%) | catalogued as COSV99442080; called by muse, mutect2, varscan2
- LRRK1 | c.5597C>T p.S1866F | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.012); catalogued as COSV99442084; called by muse, mutect2, varscan2
- LTA4H | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV57381546; called by muse, mutect2, varscan2
- LTK | c.2569C>T p.L857F | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.66); catalogued as COSV99541100; called by muse, mutect2, varscan2
- LUZP4 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1257167056, COSV64218871; called by muse, mutect2, varscan2
- LYVE1 | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.122); catalogued as COSV99811150; called by muse, mutect2, varscan2
- MACF1 | c.1178C>T p.P393L | Missense Mutation (SNP) | VAF 11/110 reads (10%) | catalogued as rs750656239, COSV100485807; called by muse, mutect2
- MAGEA3 | c.356T>A p.F119Y | Missense Mutation (SNP) | VAF 83/255 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); catalogued as COSV100939077; called by muse, mutect2, varscan2
- MAGEB16 | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.069); catalogued as COSV101303258, COSV67874280; called by muse, mutect2
- MAGEB2 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.68); PolyPhen benign (0.009); catalogued as COSV100975729; called by muse, mutect2, varscan2
- MAGEB6 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.705); catalogued as COSV66873178; called by muse, mutect2, varscan2
- MAGEC1 | c.2071C>T p.P691S | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); catalogued as rs1357386902, COSV53568374; called by muse, mutect2, varscan2
- MAGEE2 | c.767G>A p.R256K | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV100973186, COSV64898345; called by muse, mutect2, varscan2
- MAML2 | c.3128C>T p.P1043L | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV73264053; called by muse, mutect2, varscan2
- MANBA | c.2077C>T p.Q693* (on ENST00000642252; = p.Q647* on NM_005908.4) | Nonsense Mutation (SNP) | VAF 12/74 reads (16%) | catalogued as COSV99899033; called by muse, mutect2, varscan2
- MAP3K5 | c.3107A>T p.E1036V | Missense Mutation (SNP) | VAF 62/144 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100753130; called by muse, mutect2, varscan2
- MAP3K9 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs868595607, COSV101173723, COSV67123215; called by muse, mutect2, varscan2
- MAP4 | c.3029C>T p.S1010F | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53137586; called by muse, mutect2, varscan2
- MAP9 | c.1486A>T p.K496* | Nonsense Mutation (SNP) | VAF 11/58 reads (19%) | catalogued as COSV100251043; called by muse, mutect2, varscan2
- MAPK10 | c.833C>T p.S278F (on ENST00000359221 / NM_001351625.2; = p.S316F on NM_002753.5) | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as COSV60391634; called by muse, mutect2
- MCF2 | c.2437G>A p.E813K | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.348); catalogued as COSV100644992; called by muse, mutect2, varscan2
- MCF2 | c.1915C>T p.Q639* | Nonsense Mutation (SNP) | VAF 8/75 reads (11%) | catalogued as COSV100644993; called by muse, mutect2, varscan2
- MCM7 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100385084; called by muse, mutect2, varscan2
- MDGA2 | c.2902C>T p.R968* (on ENST00000399232 / NM_001113498.2; = p.R670* on NM_182830.4) | Nonsense Mutation (SNP) | VAF 7/51 reads (14%) | catalogued as COSV100637639, COSV100637642; called by muse, mutect2, varscan2
- MDGA2 | c.2901C>G p.I967M (on ENST00000399232 / NM_001113498.2; = p.I669M on NM_182830.4) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100637807; called by muse, mutect2, varscan2
- ME2 | c.1528G>A p.G510R | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754687801, COSV100360896, COSV58422378; called by muse, mutect2, varscan2
- MECOM | c.1832G>A p.G611E (on ENST00000468789 / NM_001105078.4; = p.G799E on NM_004991.4) | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs267599684, COSV52962370; called by muse, mutect2, varscan2
- MED12L | c.2940G>A p.M980I | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV99854165; called by muse, mutect2, varscan2
- MED12L | c.6413C>T p.P2138L | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs769893574, COSV99191327; called by muse, mutect2, varscan2
- MED13L | c.1658C>T p.S553F | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99929713; called by muse, mutect2, varscan2
- MED14 | c.4031C>T p.P1344L | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100247579; called by muse, mutect2, varscan2
- MED16 | c.1283C>T p.A428V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.061); catalogued as rs751728446, COSV99516095; called by muse, mutect2, varscan2
- MED25 | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV100457787; called by muse, mutect2, varscan2
- MEGF8 | c.8168C>T p.P2723L (on ENST00000251268 / NM_001271938.2; = p.P2656L on NM_001410.3) | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.081); catalogued as COSV52094487; called by muse, mutect2, varscan2
- MEIS2 | c.701G>A p.G234E (on ENST00000561208 / NM_170675.5; = p.G221E on NM_002399.3) | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV54931911, COSV54934277; called by muse, mutect2, varscan2
- MEP1A | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as COSV100042971; called by mutect2, varscan2
- MEPE | c.278G>A p.R93K | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.093); catalogued as COSV100734977; called by muse, mutect2, varscan2
- MET | c.4162G>A p.E1388K | Missense Mutation (SNP) | VAF 43/152 reads (28%) | PolyPhen benign (0); catalogued as COSV100577321; called by muse, mutect2, varscan2
- MFN1 | c.228G>A p.M76I | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV99764623; called by muse, mutect2, varscan2
- MGAT5 | c.1531T>C p.L511= | Splice Region (SNP) | VAF 19/98 reads (19%) | catalogued as rs769087376, COSV99924844; called by muse, mutect2, varscan2
- MINAR1 | c.1849C>T p.R617C | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs759948705, COSV59583795; called by muse, mutect2, varscan2
- MIPOL1 | c.1043C>T p.S348F | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100539368, COSV59381639; called by muse, mutect2, varscan2
- MLNR | c.1118G>A p.R373K | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV99519986; called by muse, mutect2, varscan2
- MMP12 | c.344C>T p.T115I | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as COSV100405038; called by muse, mutect2, varscan2
- MMP13 | c.852T>G p.C284W | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99506745; called by muse, mutect2, varscan2
- MMP21 | c.1297G>A p.G433R | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as COSV100523801; called by muse, mutect2, varscan2
- MN1 | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.23); catalogued as COSV100180036; called by muse, mutect2, varscan2
- MORC1 | c.2705C>T p.S902F | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV99227214; called by muse, mutect2, varscan2
- MORC1 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV99227217; called by muse, mutect2, varscan2
- MOV10 | c.763C>T p.P255S | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV100659711; called by muse, mutect2, varscan2
- MOV10L1 | c.3415C>T p.P1139S | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.314); catalogued as COSV99434660; called by muse, mutect2, varscan2
- MRI1 | c.923T>G p.V308G (on ENST00000040663 / NM_001031727.4; = p.V261G on NM_032285.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV99237700; called by mutect2, varscan2
- MRO | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.116); catalogued as COSV99839437; called by muse, mutect2, varscan2
- MROH9 | c.789G>A p.M263I | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.086); catalogued as COSV100882924; called by muse, mutect2, varscan2
- MRPL15 | c.868C>T p.L290F | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.08); catalogued as COSV99477597; called by muse, mutect2, varscan2
- MTA1 | c.1202C>T p.S401F | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100495392; called by muse, mutect2, varscan2
- MTF2 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.637); catalogued as COSV100940162; called by muse, mutect2, varscan2
- MTHFD2L | c.613A>T p.T205S (on ENST00000395759 / NM_001144978.2; = p.T147S on NM_001004346.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100306285; called by muse, mutect2, varscan2
- MTMR11 | c.1250C>T p.P417L (on ENST00000439741 / NM_001145862.2; = p.P345L on NM_181873.3) | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as COSV99641311; called by muse, mutect2
- MUC16 | c.29575C>T p.P9859S | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.862); catalogued as COSV67501737; called by muse, mutect2, varscan2
- MUC16 | c.26365C>T p.P8789S | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.007); catalogued as COSV101200678; called by muse, mutect2, varscan2
- MUC16 | c.23918C>T p.S7973F | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.651); catalogued as COSV101198918; called by muse, mutect2, varscan2
- MUC16 | c.22288C>T p.Q7430* | Nonsense Mutation (SNP) | VAF 20/59 reads (34%) | catalogued as COSV101200680; called by muse, mutect2, varscan2
- MUC16 | c.21586C>T p.P7196S | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.027); catalogued as rs868615219, COSV101200681; called by muse, mutect2, varscan2
- MUC16 | c.20225C>T p.P6742L | Missense Mutation (SNP) | VAF 34/168 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as COSV67493625; called by muse, varscan2
- MUC16 | c.20140T>A p.S6714T | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.094); catalogued as COSV101200683; called by muse, varscan2
- MUC16 | c.16052C>T p.S5351F | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.279); catalogued as rs535604290, COSV67486384; called by muse, mutect2, varscan2
- MUC16 | c.12584C>T p.S4195F | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.163); catalogued as COSV101198090, COSV67463278; called by muse, mutect2, varscan2
- MUC16 | c.10892C>T p.P3631L | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as COSV101200687; called by muse, mutect2, varscan2
- MUC16 | c.7208C>T p.S2403F | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as rs1357636577, COSV67447684; called by muse, mutect2, varscan2
- MUC16 | c.5425G>A p.E1809K | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated, low confidence (0.42); PolyPhen possibly damaging (0.801); catalogued as COSV101200088; called by muse, mutect2, varscan2
- MUC17 | c.848G>A p.S283N | Missense Mutation (SNP) | VAF 76/250 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100074508; called by muse, mutect2, varscan2
- MUC17 | c.4003G>A p.G1335R | Missense Mutation (SNP) | VAF 85/310 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.586); catalogued as rs1483003844, COSV60298852, COSV60310580; called by muse, mutect2, varscan2
- MUC17 | c.11431G>A p.E3811K | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.621); catalogued as COSV60284373, COSV60284948; called by muse, mutect2, varscan2
- MUC21 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV100888903; called by muse, mutect2, varscan2
- MUC5B | c.13012C>T p.P4338S | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs771499314, COSV101500620; called by muse, mutect2, varscan2
- MXRA5 | c.6346G>A p.D2116N | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV99478462; called by muse, mutect2, varscan2
- MXRA5 | c.5951G>A p.W1984* | Nonsense Mutation (SNP) | VAF 11/58 reads (19%) | catalogued as COSV99478468; called by muse, mutect2, varscan2
- MXRA5 | c.4088G>A p.G1363E | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV99478470; called by muse, varscan2
- MYB | c.1751A>T p.N584I | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV100215062; called by muse, mutect2, varscan2
- MYBPH | c.862A>C p.T288P | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV99704643; called by muse, mutect2, varscan2
- MYCBP2 | c.12353G>A p.R4118Q (on ENST00000357337; = p.R4156Q on NM_015057.5) | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.921); catalogued as rs144934192; called by muse, mutect2, varscan2
- MYCBP2 | c.9965C>G p.P3322R (on ENST00000357337; = p.P3360R on NM_015057.5) | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.9); catalogued as COSV100631265, COSV62029238; called by muse, mutect2, varscan2
- MYCBPAP | c.94G>A p.G32R | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.243); catalogued as COSV60407997; called by muse, mutect2, varscan2
- MYH11 | c.2859G>A p.L953= | Splice Region (SNP) | VAF 11/74 reads (15%) | catalogued as COSV100259770; called by muse, mutect2, varscan2
- MYH6 | c.3610G>A p.E1204K | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as rs1233225064, COSV100676858; called by muse, mutect2, varscan2
- MYH6 | c.2896G>A p.V966M | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100676859; called by muse, mutect2, varscan2
- MYMK | c.517-1G>A p.X173_splice | Splice Site (SNP) | VAF 5/42 reads (12%) | catalogued as COSV101301168; called by muse, mutect2
- MYO15A | c.1123C>T p.H375Y | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT tolerated (0.88); PolyPhen benign (0.036); catalogued as COSV99233877; called by muse, mutect2, varscan2
- MYO1F | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1220620257, COSV100596934; called by muse, mutect2, varscan2
- MYO3B | c.1081C>T p.H361Y | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV100511225; called by muse, mutect2, varscan2
- MYO5B | c.1556G>A p.G519E | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53212058, COSV53212241; called by muse, mutect2, varscan2
- MYO9B | c.2551C>T p.R851C | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs371170616; called by muse, mutect2, varscan2
- MYOC | c.1461T>A p.F487L | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV99231643; called by muse, mutect2, varscan2
- MYOCD | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as COSV100591181; called by muse, mutect2, varscan2
- MYOM2 | c.1862C>T p.S621F | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.967); catalogued as rs1188111634, COSV100038057; called by muse, mutect2, varscan2
- MYOM3 | c.2065G>A p.E689K | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.178); catalogued as rs200195822; called by muse, mutect2, varscan2
- NACA2 | c.291G>A p.W97* | Nonsense Mutation (SNP) | VAF 45/272 reads (17%) | catalogued as COSV71713100, COSV71713171; called by muse, mutect2, varscan2
- NALCN | c.2612A>G p.K871R | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99216841; called by muse, mutect2, varscan2
- NANOG | c.160C>T p.L54F | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.736); catalogued as COSV57551198, COSV99981690; called by muse, mutect2, varscan2
- NCAN | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.108); catalogued as COSV99387962; called by muse, mutect2, varscan2
- NCKAP1L | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53203336; called by muse, mutect2, varscan2
- NCOA6 | c.2014C>T p.P672S | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV100750238; called by muse, mutect2, varscan2
- NDRG4 | c.126C>T p.N42= (on ENST00000570248 / NM_001378344.1; = p.N74= on NM_020465.4 and 5 other RefSeq transcripts) | Splice Region (SNP) | VAF 7/35 reads (20%) | catalogued as COSV99262420; called by muse, mutect2, varscan2
- NDUFS1 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1383055365, COSV99260836, COSV99261290; called by mutect2, varscan2
- NEBL | c.1915C>T p.P639S | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.329); catalogued as COSV101009301; called by muse, mutect2, varscan2
- NELL2 | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.953); catalogued as COSV100420364; called by muse, mutect2, varscan2
- NEUROD4 | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.36); catalogued as rs1241017522, COSV54472486, COSV54473978; called by muse, mutect2, varscan2
- NGF | c.716G>A p.R239K | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV101049631; called by muse, mutect2, varscan2
1,372 further variants in this file (653 protein-altering or splice-affecting, 672 silent, 47 other) are not listed here.
